Somatic mutation profile of tumor specimen TCGA-EP-A2KC-01A (aliquot TCGA-EP-A2KC-01A-11D-A20W-10) from TCGA case TCGA-EP-A2KC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.1 years (22,677 days).
Specimen TCGA-EP-A2KC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54215023-3d72-4bee-adfd-ddb8e49d25e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A2KC-10A (Blood Derived Normal), aliquot TCGA-EP-A2KC-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493f0f89-03ad-4ba8-a7d9-e5fc184e8613

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 23, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, In Frame Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 15/106 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AANAT | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51686478; called by muse, mutect2, varscan2
- ACAD8 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.641); catalogued as COSV55542814; called by muse, mutect2, varscan2
- ACCSL | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV66582012, COSV66582928; called by muse, mutect2, varscan2
- ADGRL2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.037); catalogued as rs139129579; called by muse, mutect2, varscan2
- ALB | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55742855; called by muse, mutect2, varscan2
- ATP13A4 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55073622; called by muse, mutect2, varscan2
- AXDND1 | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62648905; called by muse, mutect2, varscan2
- BRSK2 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV57549348; called by muse, mutect2, varscan2
- CCN5 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV51939504; called by muse, mutect2, varscan2
- CD5L | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779754060, COSV63823209; called by muse, mutect2, varscan2
- CPNE8 | c.552T>A p.F184L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV58852494; called by muse, mutect2, varscan2
- CYP2C8 | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV64876404, COSV64879038; called by muse, mutect2, varscan2
- DNAH1 | c.10697T>C p.L3566P | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70236665; called by muse, mutect2, varscan2
- DNAH7 | c.6830A>G p.K2277R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV56787962; called by muse, mutect2, varscan2
- DNAJB4 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV66131436, COSV66132136; called by muse, mutect2, varscan2
- DOCK7 | c.4480G>A p.V1494I (on ENST00000635253 / NM_001367561.1; = p.V1463I on NM_033407.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs746518826, COSV52021964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECT2L | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368116476, COSV62885630; called by muse, mutect2, varscan2
- EPHB3 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV57809358; called by muse, mutect2, varscan2
- FARP1 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60348744; called by muse, mutect2, varscan2
- FBN1 | c.1596T>G p.D532E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57331146; called by muse, mutect2, varscan2
- FKBP11 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185599350, COSV56740333; called by muse, mutect2, varscan2
- FRA10AC1 | c.788-2A>G p.X263_splice | Splice Site (SNP) | VAF 44/88 reads (50%) | catalogued as COSV63273989; called by muse, mutect2, varscan2
- H2BC12 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63617710; called by muse, mutect2, varscan2
- KCNB2 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV73053110; called by muse, mutect2, varscan2
- KIDINS220 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs774334582, COSV56759454; called by muse, mutect2, varscan2
- LAMA1 | c.2737G>T p.V913L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV101056591, COSV67544778; called by muse, mutect2, varscan2
- LEMD3 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV57654082; called by muse, mutect2, varscan2
- LRP2 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV55575847; called by muse, mutect2, varscan2
- LRRC39 | c.431T>A p.V144D | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV61584159; called by muse, mutect2, varscan2
- MAP2K6 | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1198336138, COSV100765149; called by muse, mutect2
- MEIS3 | c.758A>T p.D253V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100520572; called by muse, mutect2, varscan2
- MEIS3 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100520574; called by muse, mutect2, varscan2
- MID1IP1 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV61231155; called by muse, mutect2, varscan2
- MTOR | c.504+2T>A p.X168_splice | Splice Site (SNP) | VAF 16/25 reads (64%) | catalogued as COSV63878650; called by muse, mutect2, varscan2
- NOX3 | c.87C>A p.D29E | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV50164348; called by muse, mutect2, varscan2
- NSFL1C | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53792642, COSV53795417; called by muse, mutect2
- NXF1 | c.1774A>T p.N592Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53676871; called by muse, mutect2, varscan2
- OAT | c.763A>T p.R255W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV64348228; called by muse, mutect2, varscan2
- PAK5 | c.1118A>T p.Y373F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62038506; called by muse, mutect2, varscan2
- PCED1A | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV62314208; called by muse, mutect2, varscan2
- PCLO | c.8728G>A p.V2910I | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs547500251, COSV61633088; called by muse, mutect2, varscan2
- PCLO | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV61668660; called by muse, mutect2, varscan2
- PLB1 | c.2015T>C p.M672T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs778270117, COSV59836131; called by muse, mutect2, varscan2
- PPP1R3A | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52883499, COSV52893683; called by muse, mutect2, varscan2
- RNF213 | c.10843C>A p.Q3615K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV60406174, COSV60409580; called by muse, mutect2, varscan2
- RNF220 | c.1399A>T p.K467* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV59192253; called by muse, mutect2, varscan2
- SGCZ | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1010565221, COSV66045541; called by muse, mutect2
- SIPA1L3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs748028255, COSV55924737; called by muse, mutect2, varscan2
- SKAP2 | c.308-1G>A p.X103_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61728180; called by muse, mutect2
- SLC2A10 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV63716081; called by muse, mutect2, varscan2
- SMARCAL1 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61923769; called by muse, mutect2, varscan2
- SPAG5 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV58804889; called by muse, mutect2, varscan2
- SPHKAP | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs868607348, COSV60895196; called by muse, mutect2, varscan2
- TAP1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1392845171, COSV62755858; called by muse, mutect2, varscan2
- TCN1 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as rs759084692, COSV57254809; called by mutect2, varscan2
- TNF | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.32); catalogued as rs747115001, COSV69305375; called by muse, mutect2, varscan2
- TP53I11 | c.188+1G>T p.X63_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57534269; called by mutect2, varscan2
- TRIP12 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52273154; called by muse, mutect2, varscan2
- ZNF185 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1463476865, COSV59278309; called by muse, mutect2, varscan2
- ZNF398 | c.518A>G p.K173R (on ENST00000475153 / NM_170686.3; = p.K2R on NM_020781.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as COSV60066901; called by muse, mutect2, varscan2
- ZNF70 | c.1324T>A p.S442T | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59533924; called by muse, mutect2, varscan2
- MFSD6 | c.727_748del p.N243Sfs*6 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- PANK4 | c.308_319dup p.D106_F107insSCLD | In Frame Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, varscan2
- YME1L1 | c.310del p.R104Vfs*15 | Frame Shift Del (DEL) | VAF 38/94 reads (40%) | called by mutect2, pindel, varscan2
- AZU1 | c.516G>T p.V172= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99297481; called by muse, mutect2, varscan2
- BICRA | c.3855G>A p.E1285= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV67604181; called by muse, mutect2, varscan2
- BIRC6 | c.8529T>A p.T2843= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101429022; called by muse, mutect2, varscan2
- BIRC6 | c.8530C>T p.L2844= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101428499, COSV70197306; called by muse, mutect2
- CAD | c.4470C>T p.A1490= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs570532952, COSV53032211; called by muse, varscan2
- COL4A5 | c.1194T>C p.P398= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV60372734; called by muse, mutect2, varscan2
- EVI2B | c.417A>G p.P139= | Silent (SNP) | VAF 22/287 reads (8%) | catalogued as COSV58365123; called by muse, mutect2
- FXR2 | c.609C>A p.R203= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- KCNK12 | c.741C>G p.L247= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1476644787, COSV59945716, COSV59946911; called by muse, mutect2, varscan2
- LRGUK | c.24C>T p.L8= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs199883304, COSV53639546; called by muse, mutect2, varscan2
- MIEF2 | c.138C>T p.A46= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1209994480, COSV58948241; called by muse, varscan2
- NAPEPLD | c.435C>T p.L145= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV58524162; called by muse, mutect2, varscan2
- NRG3 | c.1005T>C p.T335= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64543879; called by muse, mutect2, varscan2
- PCDHA7 | c.1353C>T p.N451= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs781957990, COSV65343883; called by muse, mutect2, varscan2
- PRPF4 | c.840C>T p.F280= (on ENST00000374198 / NM_001322267.2; = p.F281= on NM_004697.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs779026548, COSV65253485; called by muse, mutect2, varscan2
- PTCD1 | c.1914T>C p.F638= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52867964; called by muse, mutect2, varscan2
- RTL9 | c.1185T>A p.S395= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV71826479; called by muse, mutect2, varscan2
- SLC1A5 | c.1176C>T p.L392= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1218554735, COSV69467585; called by muse, mutect2, varscan2
- TMEM67 | c.1497T>C p.D499= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV60044754; called by muse, mutect2, varscan2
- TPH2 | c.957A>G p.E319= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV104414880, COSV61594509; called by muse, mutect2, varscan2
- WNT8A | c.933C>T p.S311= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV64231788; called by muse, mutect2, varscan2
- ZNF667 | c.1746C>T p.P582= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV52639703; called by muse, mutect2, varscan2
- ZNF804B | c.2241C>T p.H747= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1168944713, COSV60828716, COSV60857298; called by mutect2, varscan2
- GOSR2 | c.-100G>A | 5'UTR (SNP) | VAF 19/61 reads (31%) | catalogued as COSV56664831; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51621G>A | Intron (SNP) | VAF 3/12 reads (25%) | catalogued as COSV101045184; called by muse, mutect2
